Somatic mutation profile of tumor specimen TCGA-BF-AAP0-06A (aliquot TCGA-BF-AAP0-06A-11D-A397-08) from TCGA case TCGA-BF-AAP0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.4 years (14,773 days).
Specimen TCGA-BF-AAP0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a638f3b-f9aa-4aea-b76f-8df33ca594e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP0-10A (Blood Derived Normal), aliquot TCGA-BF-AAP0-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/291850b2-1716-46a2-80b0-fe0a18a860c7

The open-access MAF lists 530 somatic variants for this specimen: 334 protein-altering or splice-affecting, 187 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 187, Nonsense Mutation 22, Splice Site 5, RNA 4, Intron 4, Splice Region 2, Translation Start Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAA2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); catalogued as COSV99551736; called by muse, mutect2
- ACOXL | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV101093737; called by muse, mutect2, varscan2
- ADAM2 | c.2069T>A p.F690Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV99696864; called by muse, mutect2, varscan2
- ADAM22 | c.2274G>A p.W758* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | catalogued as rs1386627413, COSV99716005; called by muse, mutect2, varscan2
- ADAM7 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.994); catalogued as COSV51548228, COSV99443162; called by muse, mutect2
- ADD2 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100034864; called by muse, mutect2
- ADGRF2 | c.908G>A p.G303E (on ENST00000296862 / NM_001368115.2; = p.G235E on NM_153839.7) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs868775655, COSV57286895; called by muse, mutect2, varscan2
- ADGRL2 | c.2617C>T p.R873C (on ENST00000370717 / NM_001366005.1; = p.R860C on NM_012302.4) | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777702018, COSV54696530; called by muse, mutect2, varscan2
- AKAP11 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV50295628; called by muse, mutect2
- AKAP6 | c.5629G>A p.E1877K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs779609551, COSV99798878; called by mutect2, varscan2
- ALOX5 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758819437, COSV100979981; called by muse, mutect2, varscan2
- AMMECR1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99466363; called by muse, mutect2, varscan2
- ANK3 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV99778635; called by muse, mutect2
- ANKRD33 | c.619C>T p.P207S (on ENST00000340970 / NM_001304459.2; = p.P332S on NM_182608.4) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100001137; called by muse, mutect2
- APOL1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs199608929, COSV100045942; called by muse, mutect2, varscan2
- ARHGEF17 | c.5885C>T p.P1962L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV55235845; called by muse, mutect2, varscan2
- ARHGEF35 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1286102013, COSV100967676; called by muse, mutect2, varscan2
- ARMC4 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV100536430; called by muse, mutect2, varscan2
- ARMCX3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868995472, COSV100362190; called by muse, mutect2, varscan2
- ASH1L | c.6644G>A p.G2215E (on ENST00000368346 / NM_001366177.2; = p.G2210E on NM_018489.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100853181; called by muse, mutect2, varscan2
- ATAD2B | c.343T>A p.W115R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99477089; called by muse, mutect2, varscan2
- BRINP1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs867961690, COSV99774677; called by muse, mutect2, varscan2
- BRWD3 | c.4270G>A p.E1424K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100955728; called by muse, mutect2, varscan2
- C17orf80 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52146814; called by muse, mutect2, varscan2
- CACNG6 | c.688A>T p.I230F (on ENST00000252729 / NM_145814.1; = p.I159F on NM_031897.2) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99403299; called by muse, mutect2, varscan2
- CARD11 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV100712215; called by muse, mutect2, varscan2
- CARMIL3 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1480239369, COSV57728721; called by muse, mutect2
- CCDC39 | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV99867567; called by muse, mutect2, varscan2
- CCR8 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as rs772838383, COSV100413024; called by muse, mutect2, varscan2
- CCT8L2 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV63463204; called by muse, mutect2
- CD300LD | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100032318; called by muse, mutect2
- CDH3 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as rs1428634638, COSV99867713; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2, varscan2
- CDKL5 | c.2987C>T p.S996F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV101183722; called by muse, mutect2
- CDKN2AIP | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1335222497, COSV100187547; called by muse, mutect2, varscan2
- CFAP54 | c.6859G>A p.E2287K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs1365372828, COSV100732995; called by muse, mutect2, varscan2
- CFHR2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV66380777; called by muse, mutect2, varscan2
- CFTR | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99134396; called by muse, mutect2, varscan2
- CHRD | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.934); catalogued as COSV99200254; called by muse, mutect2, varscan2
- CHRNA3 | c.1241A>T p.N414I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV100467947; called by muse, mutect2, varscan2
- CHRNA6 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52379721; called by muse, mutect2, varscan2
- CHRNA9 | c.727A>C p.N243H | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038846; called by muse, mutect2, varscan2
- CHRND | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV51317433, COSV51318217; called by muse, mutect2, varscan2
- CHST1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57322912, COSV57323719; called by muse, mutect2, varscan2
- CIT | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs750567021, COSV55873718; called by mutect2, varscan2
- CLSTN3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs867630711, COSV56936436; called by muse, mutect2, varscan2
- CNOT8 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs774772048, COSV53585801; called by muse, mutect2, varscan2
- COL10A1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99684094; called by muse, mutect2, varscan2
- COL28A1 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs141928495, COSV68081743; called by muse, mutect2, varscan2
- COX7B | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV63781391; called by muse, mutect2, varscan2
- COX7B | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100968784; called by muse, mutect2
- CPAMD8 | c.593C>T p.T198I (on ENST00000651564; = p.T151I on NM_015692.5) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as COSV99359036; called by muse, mutect2, varscan2
- CR2 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769404342, COSV100889542, COSV104424433; called by mutect2, varscan2
- CREBBP | c.7145C>T p.S2382F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1567259408, COSV52119630, COSV52139873; called by muse, mutect2, varscan2
- CRYBA1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99836949; called by muse, mutect2
- CTAG2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs782251849, COSV99908812; called by muse, mutect2
- CYB5D2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100028896; called by muse, mutect2, varscan2
- CYP11B1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV52825422, COSV52827224; called by muse, mutect2
- CYP1A1 | c.533T>C p.M178T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.357); catalogued as COSV101122233; called by muse, mutect2, varscan2
- CYP4A11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60222200; called by muse, mutect2, varscan2
- CYP4F2 | c.286T>A p.S96T | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV50000759; called by muse, mutect2, varscan2
- DCDC2 | c.527A>T p.K176I | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101015953; called by muse, mutect2, varscan2
- DCSTAMP | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.023); catalogued as COSV52580650, COSV99886168; called by muse, mutect2, varscan2
- DEPDC1B | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54007937, COSV54010402; called by muse, mutect2, varscan2
- DHX37 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100439042; called by muse, mutect2, varscan2
- DIDO1 | c.4544C>T p.S1515L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143908148, COSV56630316; called by muse, mutect2, varscan2
- DIDO1 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV56619644; called by muse, mutect2, varscan2
- DLGAP3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758641286, COSV52396489; called by mutect2, varscan2
- DMD | c.8873G>A p.G2958E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.086); catalogued as COSV100626155; called by muse, mutect2, varscan2
- DNAH1 | c.7951G>A p.E2651K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70232568; called by muse, mutect2, varscan2
- DNAH7 | c.10054G>A p.D3352N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100413907; called by muse, mutect2, varscan2
- DNAH7 | c.4740G>A p.M1580I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV56772128; called by muse, mutect2, varscan2
- DNAH8 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs752766661, COSV100543640; called by muse, mutect2, varscan2
- DNHD1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99599553; called by muse, mutect2
- ECE1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1243917410, COSV99941460; called by muse, mutect2, varscan2
- ECT2L | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62883996; called by muse, mutect2, varscan2
- EDNRB | c.536C>T p.P179L (on ENST00000377211 / NM_001201397.1; = p.P89L on NM_000115.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57524395; called by muse, mutect2, varscan2
- EHD2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs149075256; called by muse, mutect2, varscan2
- EI24 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452364929, COSV99628903; called by muse, mutect2
- ELP5 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV100020921; called by muse, mutect2, varscan2
- EML5 | c.3678G>A p.G1226= | Splice Region (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100715143, COSV61343291; called by muse, mutect2
- EPHA7 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs757798599, COSV65195603; called by muse, mutect2, varscan2
- EPHB1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959853730, COSV67657761; called by muse, mutect2
- EPHB1 | c.2489A>G p.N830S | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101212765; called by muse, mutect2, varscan2
- EYA4 | c.1912C>T p.Q638* (on ENST00000531901 / NM_001301013.1; = p.Q632* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100765303; called by muse, mutect2
- F13A1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99342384; called by muse, mutect2, varscan2
- FAM20A | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs772882502, COSV99873223; called by muse, mutect2, varscan2
- FAM83A | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.197); catalogued as COSV52684775; called by muse, mutect2, varscan2
- FBLN7 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99734731; called by muse, mutect2, varscan2
- FBXO45 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV61147233; called by muse, mutect2, varscan2
- FBXW12 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs199674621, COSV99601483; called by muse, mutect2, varscan2
- FCRL5 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV100708596; called by muse, mutect2
- FLG | c.6397G>A p.E2133K | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.159); catalogued as COSV64238938; called by muse, mutect2, varscan2
- FLNC | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1343786191, COSV100367696; called by muse, mutect2, varscan2
- FLNC | c.6130G>A p.V2044M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100367697; called by muse, mutect2, varscan2
- FLRT1 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV99734758; called by muse, mutect2
- FMNL1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1295137518, COSV100056244; called by muse, mutect2, varscan2
- FNIP2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV100032251; called by muse, mutect2, varscan2
- FOXL1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as rs1383016177, COSV57215411; called by muse, mutect2
- FRMD4B | c.2460T>G p.S820R | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV101273349; called by muse, mutect2
- FSHR | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100436666; called by muse, mutect2
- FSTL5 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as rs765439121, COSV100053272, COSV60187777; called by muse, mutect2, varscan2
- FYB1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100685020; called by muse, mutect2, varscan2
- GABRA2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62912331; called by muse, mutect2, varscan2
- GABRA6 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV50877458, COSV50877753; called by muse, mutect2
- GABRB1 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs1463466456, COSV99780470; called by muse, mutect2
- GFRAL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868599487, COSV61228767, COSV61234756; called by muse, mutect2, varscan2
- GIMAP6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1205818749, COSV100188119, COSV100188274; called by muse, mutect2, varscan2
- GLI2 | c.1294G>A p.D432N (on ENST00000361492 / NM_001374353.1; = p.D449N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs13427953, COSV58044729; called by muse, mutect2
- GPR176 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs773339133, COSV100137011; called by muse, mutect2, varscan2
- GRID1 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100022338; called by muse, mutect2, varscan2
- GRIK2 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868337042, COSV100023825; called by muse, mutect2, varscan2
- HAUS4 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.246); catalogued as COSV52826994, COSV99246774, COSV99247062; called by muse, mutect2, varscan2
- HECW2 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as rs371715457; called by muse, mutect2, varscan2
- HEPACAM | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100005504; called by muse, mutect2, varscan2
- HNF4A | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as COSV100291143; called by muse, mutect2, varscan2
- HUWE1 | c.12946G>T p.G4316C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99470897; called by muse, mutect2, varscan2
- IGKV2D-28 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV101494567; called by mutect2, varscan2
- INHBA | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99637249; called by muse, varscan2
- INTS6L | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878033; called by muse, mutect2
- KCNK10 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56640184; called by muse, mutect2
- KCNQ3 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.123); catalogued as COSV101195751; called by muse, mutect2, varscan2
- KIF1C | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs139942468; called by muse, mutect2
- KIF4B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV70530146; called by muse, mutect2, varscan2
- KIF5A | c.2326T>C p.S776P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99672544; called by muse, mutect2, varscan2
- KIF5B | c.715A>G p.S239G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV100191502; called by muse, mutect2, varscan2
- KIR2DL1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs749166231, COSV52410003; called by muse, mutect2, varscan2
- KIR3DL1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV100428350; called by muse, mutect2, varscan2
- KIRREL2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99383653; called by muse, mutect2, varscan2
- KLHL13 | c.1760A>T p.N587I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV99451174; called by muse, mutect2, varscan2
- KRT23 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV99266126; called by muse, mutect2
- KRT25 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); catalogued as rs990586331, COSV100379835; called by muse, mutect2, varscan2
- KRT75 | c.498+1G>A p.X166_splice | Splice Site (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99359233; called by muse, mutect2
- KRTAP5-3 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.282); catalogued as rs78764884, COSV101294495; called by muse, varscan2
- KRTDAP | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV100139233; called by muse, mutect2
- LAMA2 | c.3260G>A p.G1087D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370212; called by muse, mutect2, varscan2
- LAMC2 | c.1100C>A p.S367* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV51454211, COSV99917150; called by mutect2, varscan2
- LGALS13 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1272808677, COSV99694883; called by muse, mutect2, varscan2
- LGR6 | c.2765G>A p.G922E (on ENST00000367278 / NM_001017403.1; = p.G870E on NM_021636.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV55165536; called by muse, mutect2, varscan2
- LILRA5 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100006784, COSV56642105; called by muse, mutect2
- LILRB2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs1417874960, COSV58746122; called by muse, mutect2, varscan2
- LONRF2 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.789); catalogued as COSV66539252; called by muse, mutect2, varscan2
- LRRC49 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV99537048; called by muse, mutect2
- MACC1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs778210684, COSV60540733; called by muse, mutect2, varscan2
- MAGEC3 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV68924221; called by muse, mutect2, varscan2
- MAP4K3 | c.2542-1G>A p.X848_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99810054; called by muse, mutect2, varscan2
- MAP4K4 | c.1985G>A p.R662K (on ENST00000347699 / NM_001242559.2; = p.R577K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.89); PolyPhen probably damaging (0.977); catalogued as COSV100153569; called by muse, mutect2
- MAST4 | c.5642G>A p.R1881Q (on ENST00000403625 / NM_001164664.2; = p.R1692Q on NM_015183.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs372106522; called by muse, mutect2, varscan2
- MCOLN2 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99393633; called by muse, mutect2, varscan2
- MCTS1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100989140; called by muse, mutect2, varscan2
- MECOM | c.2654C>T p.S885L (on ENST00000468789 / NM_001105078.4; = p.S1073L on NM_004991.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.292); catalogued as COSV99244206; called by muse, mutect2, varscan2
- MED1 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 10/159 reads (6%) | catalogued as COSV100327499; called by muse, mutect2
- MKLN1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100759719; called by muse, mutect2, varscan2
- MLLT6 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.996); catalogued as rs891443028; called by muse, mutect2, varscan2
- MLN | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs368261744, COSV56474905; called by muse, mutect2
- MMP1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100187810; called by muse, varscan2
- MMP16 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1173842074, COSV54171650, COSV99686433; called by muse, mutect2, varscan2
- MMRN2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV64401549; called by muse, mutect2
- MORC1 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99225316; called by muse, mutect2, varscan2
- MTA1 | c.1998G>A p.R666= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as rs782558249, COSV58758079; called by muse, mutect2
- MTSS1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100274499; called by muse, mutect2, varscan2
- MUC16 | c.24454G>A p.E8152K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.263); catalogued as COSV67481040; called by muse, mutect2, varscan2
- MUC16 | c.13117C>T p.P4373S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV101198446, COSV67483178; called by muse, mutect2, varscan2
- MUC16 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs777666536, COSV67453248; called by muse, mutect2
- MUC16 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67445914; called by muse, mutect2
- MUC3A | c.8502G>A p.M2834I | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100114095; called by muse, mutect2, varscan2
- MUC4 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100639867; called by muse, mutect2
- MXRA5 | c.2313A>G p.I771M | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99476012; called by muse, mutect2, varscan2
- MYO5B | c.4402G>A p.G1468S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99543841; called by muse, mutect2, varscan2
- MYT1L | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV101219203; called by muse, mutect2, varscan2
- NCR3 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV53002449; called by muse, mutect2, varscan2
- NDN | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1566793269, COSV59358849; called by muse, mutect2, varscan2
- NEB | c.19616G>A p.R6539Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779983347, COSV50857594; called by muse, mutect2
- NEB | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99416246; called by muse, mutect2, varscan2
- NEFH | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV100151313; called by muse, varscan2
- NELFE | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1306040972, COSV100952624; called by muse, mutect2
- NELFE | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs1314841229, COSV100952625; called by muse, mutect2
- NEUROD4 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99669763; called by muse, mutect2, varscan2
- NLRP10 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV60779220; called by muse, mutect2
- NLRP7 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60181673; called by muse, mutect2, varscan2
- NLRP8 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99404830; called by muse, mutect2, varscan2
- NOC2L | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | catalogued as COSV58531386; called by muse, mutect2, varscan2
- NPNT | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV99974753; called by muse, mutect2
- NUDT2 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663532; called by muse, mutect2, varscan2
- NUP133 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as rs753547351, COSV54568158, COSV99772635; called by muse, mutect2
- OR10K1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56874652, COSV99193274; called by muse, mutect2, varscan2
- OR13C9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1449453306, COSV52241779, COSV52243398; called by muse, mutect2, varscan2
- OR2L3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63454596; called by muse, varscan2
- OR3A2 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101375039; called by muse, mutect2
- OR4C13 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV101634147; called by muse, mutect2, varscan2
- OR4K14 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV59294543, COSV99043330; called by muse, mutect2
- OR4Q3 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59178862; called by muse, mutect2
- OR5H15 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377308175, COSV62947393; called by muse, mutect2
- OR5K1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60303539; called by muse, mutect2, varscan2
- OR5L2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV65723523, COSV65724355; called by muse, mutect2, varscan2
- OR5T1 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs764663191, COSV100478782, COSV57303493; called by muse, mutect2
- OR6C6 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs956997118, COSV64456259; called by muse, mutect2
- OR8J3 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100040604, COSV100040796, COSV56881853; called by muse, mutect2, varscan2
- ORAI3 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99352544; called by muse, mutect2, varscan2
- OTOA | c.2191C>T p.P731S (on ENST00000286149; = p.P717S on NM_144672.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.086); catalogued as COSV99623806; called by muse, mutect2
- OTOA | c.2192C>T p.P731L (on ENST00000286149; = p.P717L on NM_144672.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99623812; called by muse, mutect2
- OTOGL | c.2372T>C p.L791P (on ENST00000547103; = p.L782P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.789); catalogued as COSV101509035; called by muse, mutect2, varscan2
- OTUD3 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1175353265, COSV100909000; called by muse, mutect2, varscan2
- P2RY8 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101183950; called by muse, mutect2
- PARP14 | c.5031G>C p.E1677D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101506236, COSV71735241; called by muse, mutect2
- PARP6 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99535833; called by muse, mutect2
- PATJ | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100333339; called by muse, mutect2, varscan2
- PCDHA1 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs781785212, COSV100974283; called by muse, mutect2, varscan2
- PCDHA6 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV65342815; called by muse, mutect2, varscan2
- PCLO | c.14393C>T p.S4798L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100427364, COSV61626787, COSV61652870; called by muse, mutect2, varscan2
- PCLO | c.11587G>A p.E3863K | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61621952; called by muse, mutect2, varscan2
- PDE8B | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99366266; called by muse, mutect2, varscan2
- PGLYRP4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100668320; called by muse, mutect2, varscan2
- PHF20L1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1563825344, COSV99620548; called by muse, mutect2
- PLA2G3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV99311379; called by muse, mutect2
- PLBD2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV99785213; called by muse, mutect2, varscan2
- PLCE1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV53347412, COSV53353511; called by muse, mutect2
- PLCH2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99615667; called by muse, mutect2
- PLEKHA6 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as COSV99691642; called by muse, mutect2
- PLXNA4 | c.2843T>C p.L948P | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs548914859, COSV100322849; called by muse, mutect2, varscan2
- PMFBP1 | c.2694G>A p.W898* (on ENST00000537465; = p.W893* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99400332; called by muse, mutect2
- POPDC3 | c.618T>A p.D206E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV99633430; called by muse, mutect2
- PRAMEF2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.394); catalogued as COSV99534940; called by muse, mutect2
- PRUNE2 | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as rs1399514250, COSV100944264; called by muse, mutect2, varscan2
- PSMB11 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943512; called by muse, mutect2, varscan2
- PSMD7 | c.189A>C p.K63N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV99542570; called by muse, mutect2
- PZP | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV104432743, COSV54367253, COSV99736611; called by muse, mutect2, varscan2
- RAB1B | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100270598; called by muse, mutect2, varscan2
- RAMP2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53822837; called by muse, mutect2, varscan2
- RBM25 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as COSV99998475; called by muse, mutect2
- RBM47 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV99920250; called by muse, mutect2
- RELN | c.9862G>A p.G3288S | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV59035558; called by muse, mutect2, varscan2
- REPIN1 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1388637702, COSV101262586; called by muse, mutect2
- RGS21 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV101313991; called by muse, mutect2
- RILPL1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775158221, COSV100525958; called by muse, mutect2, varscan2
- RND1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV100552096; called by muse, mutect2
- RNF113A | c.584G>A p.W195* | Nonsense Mutation (SNP) | VAF 16/159 reads (10%) | catalogued as COSV101006982; called by muse, mutect2, varscan2
- RSPH4A | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99993969; called by muse, mutect2
- RSU1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as rs780510735, COSV100590269; called by muse, mutect2, varscan2
- RYR2 | c.11209G>A p.A3737T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100768512; called by muse, mutect2
- SAGE1 | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.155); catalogued as rs143132398, COSV100186789; called by muse, mutect2, varscan2
- SAMD3 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100148140, COSV60775512; called by muse, mutect2
- SCMH1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100401421; called by muse, mutect2, varscan2
- SCML2 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99318643; called by muse, varscan2
- SCN10A | c.5188G>A p.E1730K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV71862376; called by muse, mutect2
- SCN1A | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs777631884, COSV100319258, COSV57678004; ClinVar: uncertain significance; called by mutect2, varscan2
- SCN2A | c.5180G>A p.G1727E | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as COSV99330390; called by muse, mutect2, varscan2
- SCN9A | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100311724; called by muse, mutect2, varscan2
- SERPINA3 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV101261620; called by muse, mutect2, varscan2
- SH2D1A | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63579679; called by muse, mutect2, varscan2
- SHOX | c.554T>C p.L185S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV100478823; called by muse, mutect2
- SLAMF6 | c.860C>T p.S287L (on ENST00000368057 / NM_001184714.2; = p.S286L on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs1489060047, COSV63588646; called by muse, mutect2, varscan2
- SLC12A5 | c.1463+1G>A p.X488_splice (on ENST00000454036 / NM_001134771.2; = p.X465_splice on NM_020708.5) | Splice Site (SNP) | VAF 17/121 reads (14%) | catalogued as COSV99715488; called by muse, mutect2, varscan2
- SLC13A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs867764394, COSV52009873, COSV52015253; called by muse, mutect2, varscan2
- SLC17A9 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64847498; called by muse, mutect2, varscan2
- SLC1A3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV99467130; called by muse, mutect2, varscan2
- SLC25A12 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs763635116, COSV99784746; called by muse, mutect2, varscan2
- SLC26A3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100384863; called by muse, mutect2, varscan2
- SLC26A3 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV100384865; called by muse, mutect2, varscan2
- SLC2A14 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV61586980; called by muse, mutect2, varscan2
- SLC5A2 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1047021581, COSV100393030; called by muse, mutect2, varscan2
- SLC6A5 | c.1128-1G>A p.X376_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100116527; called by muse, mutect2
- SLC9A2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as rs61743555, COSV52128997; called by muse, mutect2, varscan2
- SMARCC2 | c.2758-1G>A p.X920_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as rs1341936924, COSV99519252; called by muse, mutect2, varscan2
- SMARCD3 | c.1262A>G p.Q421R (on ENST00000262188 / NM_001003801.2; = p.Q408R on NM_003078.4) | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV99222818; called by muse, mutect2
- SPOCK3 | c.914G>A p.W305* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV62737743; called by mutect2, varscan2
- SSH1 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs778512980, COSV100425368; called by muse, mutect2
- STXBP5L | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs746414321, COSV99872426; called by muse, mutect2, varscan2
- SULT1C4 | c.33T>A p.F11L | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99731486; called by muse, mutect2, varscan2
- SUPV3L1 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV100669529; called by muse, mutect2
- SYNE1 | c.2754G>A p.W918* (on ENST00000367255 / NM_182961.4; = p.W925* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99555575; called by muse, mutect2
- SYT9 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV100607654; called by muse, mutect2, varscan2
- TACC2 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100551722; called by muse, mutect2
- TARBP2 | c.148C>T p.L50F (on ENST00000266987 / NM_134323.2; = p.L29F on NM_004178.4) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99908411; called by muse, mutect2
- TCP11L2 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.893); catalogued as COSV100135210; called by muse, mutect2, varscan2
- TENM1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100949268; called by muse, mutect2, varscan2
- TENM4 | c.4034C>T p.A1345V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV53661541, COSV99571948; called by muse, mutect2, varscan2
- TET3 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99996212; called by muse, mutect2
- TEX15 | c.5422C>T p.L1808F (on ENST00000256246; = p.L2191F on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56345608, COSV56349477; called by muse, mutect2, varscan2
- TEX2 | c.3119C>T p.P1040L (on ENST00000583097 / NM_001288733.2; = p.P1047L on NM_018469.5) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366842; called by muse, mutect2
- TMEM37 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.246); catalogued as COSV50026740; called by muse, mutect2
- TMPRSS11F | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs377605520; called by mutect2, varscan2
- TPO | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV61100046; called by muse, mutect2, varscan2
- TPRG1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61466778; called by muse, mutect2
- TRANK1 | c.8395G>A p.E2799K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.101); catalogued as rs777944962, COSV100081809, COSV57158073; called by muse, mutect2, varscan2
- TRIM16L | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV101192584; called by muse, mutect2
- TRPC7 | c.899G>A p.W300* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100725533; called by mutect2, varscan2
- TRPM7 | c.3568C>T p.H1190Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV57919186; called by muse, mutect2, varscan2
- TSPYL6 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100336340; called by muse, mutect2, varscan2
- TTC27 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs755121558, COSV58655694; called by muse, mutect2, varscan2
- TTN | c.59855C>T p.T19952I (on ENST00000591111; = p.T12528I on NM_003319.4) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV100598129; called by muse, mutect2, varscan2
- TTN | c.16082G>A p.R5361Q (on ENST00000591111; = p.R4434Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | PolyPhen possibly damaging (0.75); catalogued as rs374742663, COSV60318230; called by muse, mutect2, varscan2
- TTN | c.12224G>A p.R4075K (on ENST00000591111; = p.R4029K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100598140, COSV60152392; called by muse, mutect2, varscan2
- UGT1A5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1357928110, COSV59380995; called by muse, mutect2, varscan2
- ULK4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100090821; called by muse, mutect2
- UPF2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV62660526; called by muse, mutect2
- USP29 | c.1913G>A p.R638K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs764776153, COSV99517775; called by mutect2, varscan2
- VAMP7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1439223778, COSV99387752; called by muse, mutect2, varscan2
- VBP1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99660735; called by muse, mutect2
- VEGFC | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs1316686549, COSV99709536; called by muse, mutect2
- VGLL3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV67353045; called by muse, mutect2, varscan2
- VWF | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1322647015, COSV99778255; called by muse, mutect2, varscan2
- WWC3 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV101081127; called by muse, mutect2, varscan2
- XIRP2 | c.1522G>A p.D508N (on ENST00000628543; = p.D683N on NM_152381.6) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV99739311; called by muse, mutect2, varscan2
- XIRP2 | c.6695C>T p.S2232F (on ENST00000628543; = p.S2407F on NM_152381.6) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54694622, COSV54728382; called by muse, mutect2, varscan2
- YES1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100099313, COSV58853694; called by muse, mutect2, varscan2
- ZBED2 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99342466; called by muse, mutect2, varscan2
- ZBED2 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as rs1317880109, COSV51916357; called by muse, mutect2, varscan2
- ZBED9 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.885); catalogued as rs1240047379, COSV71729257; called by muse, mutect2, varscan2
- ZBTB33 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58533600, COSV58534599; called by muse, mutect2, varscan2
- ZDHHC7 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100568737; called by muse, mutect2, varscan2
- ZNF280B | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1245935689, COSV100840201; called by muse, mutect2
- ZNF280C | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100921194, COSV63968862; called by muse, mutect2
- ZNF292 | c.6400C>T p.H2134Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60537367; called by muse, mutect2, varscan2
- ZNF41 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491884, COSV57443274; called by muse, mutect2, varscan2
- ZNF528 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64619466; called by muse, mutect2
- ZNF573 | c.718C>T p.H240Y (on ENST00000536220 / NM_001172692.1; = p.H182Y on NM_152360.3) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59823521; called by muse, mutect2, varscan2
- ZNF639 | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100418390; called by muse, mutect2, varscan2
- ZNF721 | c.1325T>G p.F442C (on ENST00000338977; = p.F454C on NM_133474.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781804076, COSV100167114; called by muse, mutect2, varscan2
- ZNF780B | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV55462252; called by muse, mutect2
- ZNF98 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV63334593, COSV63337169; called by muse, mutect2, varscan2
- ZPBP | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249184; called by muse, mutect2
- ZZEF1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238961778, COSV101067575; called by muse, mutect2, varscan2
- ASAH2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.661); called by muse, mutect2
- CDH22 | c.239_240delinsA p.P80Hfs*32 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2*
- DLGAP3 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- DNAH5 | c.5458G>A p.E1820K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2
- KIR2DL3 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KIR2DS4 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- MRC1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF15 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 41/428 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RAI14 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- ADAM2 | c.1806G>A p.R602= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV55861261; called by muse, mutect2, varscan2
- ADAM2 | c.33C>T p.L11= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55863316; called by muse, mutect2, varscan2
- ADAMTS18 | c.1833C>T p.F611= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV51400235; called by muse, mutect2, varscan2
- ADCY2 | c.1926C>T p.I642= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs1020710480, COSV100602003; called by muse, mutect2, varscan2
- ADGRG4 | c.2652T>A p.V884= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV99794597; called by muse, mutect2
- ALPK3 | c.4317C>T p.G1439= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV51940241; called by muse, mutect2
- ALPL | c.1167C>T p.T389= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs772412576, COSV100876172; called by muse, mutect2, varscan2
- AMBRA1 | c.729C>T p.F243= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100093007; called by muse, mutect2, varscan2
- AMDHD1 | c.702G>A p.E234= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99900217; called by muse, mutect2, varscan2
- ANK3 | c.5064C>T p.V1688= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV99778632; called by muse, mutect2, varscan2
- ART1 | c.135C>T p.S45= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99167126; called by muse, mutect2, varscan2
- ASPHD2 | c.213C>T p.F71= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs749565197, COSV53218297; called by mutect2, varscan2
- ATRX | c.6396A>G p.V2132= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100970192; called by muse, mutect2
- BAHD1 | c.1596C>T p.A532= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101346718; called by muse, mutect2, varscan2
- BCAN | c.540C>T p.A180= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV61257207; called by muse, mutect2
- BDKRB1 | c.183C>T p.V61= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99387762; called by muse, mutect2
- BIVM-ERCC5 | c.3261C>T p.S1087= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV63245131; called by muse, mutect2, varscan2
- BPIFC | c.1068C>T p.F356= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV55914841; called by muse, mutect2, varscan2
- BPTF | c.1620G>A p.K540= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100074257; called by muse, mutect2, varscan2
- CACNA1E | c.1620C>T p.F540= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1394247968, COSV62441138; called by muse, mutect2, varscan2
- CACNA1S | c.1647G>A p.V549= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100754727; called by muse, mutect2
- CALCR | c.492G>A p.V164= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100810430; called by muse, mutect2, varscan2
- CALHM2 | c.516C>T p.F172= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99588279; called by muse, mutect2, varscan2
- CCDC122 | c.321T>C p.L107= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99865852; called by muse, mutect2, varscan2
- CCDC83 | c.117C>T p.A39= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs961807443, COSV54704151, COSV99721421; called by muse, mutect2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs763870346, COSV63129316; called by muse, mutect2, varscan2
- CHD5 | c.2614C>T p.L872= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99312703; called by muse, mutect2, varscan2
- CHD7 | c.6369C>T p.S2123= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101418036; called by muse, mutect2, varscan2
- CHMP4C | c.456G>A p.R152= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV51926309; called by muse, mutect2, varscan2
- CNPY3 | c.237C>T p.I79= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100863582; called by muse, mutect2, varscan2
- COL7A1 | c.3081C>T p.S1027= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1331854035, COSV100095294; called by muse, mutect2
- COLEC12 | c.1785G>A p.Q595= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101231980; called by muse, mutect2, varscan2
- CSMD2 | c.5196C>T p.A1732= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1273117392, COSV99586890; called by muse, mutect2
- CST1 | c.243G>A p.V81= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs1378092159, COSV100494301; called by muse, mutect2, varscan2
- CTTNBP2 | c.2082C>T p.S694= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV50390057; called by muse, mutect2, varscan2
- CWH43 | c.1860G>A p.L620= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV99892939, COSV99893807; called by muse, mutect2, varscan2
- CYP17A1 | c.1002G>A p.Q334= | Silent (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- CYP2C19 | c.1065C>T p.V355= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100990268; called by muse, mutect2
- CYP4F12 | c.297C>T p.I99= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs369774036; called by muse, mutect2
- CYTIP | c.294G>A p.Q98= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99938646; called by muse, mutect2
- DAXX | c.2049C>T p.S683= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99801595; called by muse, mutect2, varscan2
- DDO | c.591C>T p.F197= (on ENST00000368924 / NM_001368172.1; = p.F138= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs954708706, COSV100927820; called by muse, mutect2, varscan2
- DNAJC16 | c.1530C>T p.L510= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- DSCAM | c.327G>A p.G109= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as COSV68638075; called by muse, mutect2
- EFHC1 | c.1284C>T p.S428= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV64137951; called by muse, mutect2
- EHD1 | c.717C>T p.S239= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100276883, COSV100277240; called by muse, mutect2, varscan2
- ELK3 | c.105C>T p.L35= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99957520; called by muse, mutect2
- ELP5 | c.525C>T p.G175= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1197639298, COSV100020920; called by muse, mutect2
- ENTPD6 | c.393C>T p.T131= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV100736996; called by muse, mutect2, varscan2
- EPHA6 | c.2244G>A p.G748= (on ENST00000389672 / NM_001080448.3; = p.G140= on NM_173655.4) | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV67562555; called by muse, mutect2
- EPHA6 | c.2661T>A p.G887= (on ENST00000389672 / NM_001080448.3; = p.G279= on NM_173655.4) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV101061080; called by muse, mutect2, varscan2
- ETNK1 | c.957C>T p.F319= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1426843432, COSV99860554; called by muse, mutect2, varscan2
- EVL | c.531C>T p.V177= (on ENST00000402714 / NM_001330221.2; = p.V179= on NM_016337.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101233047; called by muse, mutect2, varscan2
- F8 | c.5916C>T p.I1972= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV64276008; called by muse, mutect2, varscan2
- FAM227B | c.708C>T p.F236= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100174567; called by muse, mutect2
- FAM53C | c.198C>T p.N66= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99524254; called by muse, mutect2, varscan2
- FAT3 | c.5886C>T p.F1962= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99962790; called by muse, mutect2, varscan2
- FAT4 | c.8997G>A p.K2999= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100627442, COSV58702343; called by muse, mutect2, varscan2
- FBLN5 | c.318G>A p.T106= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV50902566; called by muse, mutect2
- FBN1 | c.4353C>T p.S1451= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV57330475; called by muse, mutect2
- FBXL18 | c.1335G>C p.P445= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101212026; called by muse, mutect2, varscan2
- FBXO42 | c.180C>T p.S60= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100981666; called by muse, mutect2, varscan2
- FBXW12 | c.876G>A p.K292= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99601477; called by muse, mutect2, varscan2
- FCRL1 | c.159C>T p.C53= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100839732; called by muse, mutect2, varscan2
- FCRL5 | c.1395C>T p.S465= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs926826526, COSV62521968; called by muse, mutect2
- FNDC1 | c.5385C>T p.F1795= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as rs571734975, COSV51932133; called by muse, mutect2
- FTSJ3 | c.1116G>A p.L372= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV100037204; called by muse, mutect2
- FYN | c.1161C>T p.I387= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV99991244; called by muse, mutect2
- GAB3 | c.1338G>A p.R446= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV100850429; called by muse, mutect2, varscan2
- GABRB2 | c.1422G>A p.L474= (on ENST00000274547; = p.L436= on NM_000813.3) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV50919647; called by muse, mutect2, varscan2
- GALK1 | c.681C>T p.V227= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99563506; called by muse, mutect2, varscan2
- GCDH | c.661C>T p.L221= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV53368353, COSV99535760; called by muse, mutect2, varscan2
- GIN1 | c.843A>G p.K281= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV101204279; called by muse, mutect2, varscan2
- GPN2 | c.183C>T p.G61= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100658708, COSV64652855; called by muse, mutect2
- GPR179 | c.90G>A p.R30= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs746596629; called by mutect2, varscan2
- GPR61 | c.792G>A p.T264= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs148279758; called by muse, mutect2, varscan2
- GPX5 | c.558C>T p.F186= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV69079594; called by muse, mutect2, varscan2
- GRM3 | c.2001C>T p.A667= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs150150295; called by muse, mutect2
- HCFC1 | c.1449C>T p.V483= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs781938666, COSV100128547; called by muse, mutect2, varscan2
- HDAC2 | c.513C>T p.V171= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100892561; called by muse, mutect2
- IDO2 | c.750G>A p.G250= (on ENST00000389060; = p.G263= on NM_194294.2) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs750242472, COSV100584586, COSV58425012; called by muse, mutect2, varscan2
- IGHV1-58 | c.174G>A p.Q58= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs782256872; called by muse, mutect2
- IGHV3-33 | c.144C>T p.F48= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs543937882; called by muse, varscan2
- IGHV3-43 | c.183G>A p.G61= | Silent (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- IL10RA | c.1620C>T p.S540= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99922905; called by mutect2, varscan2
- INSIG1 | c.744C>T p.L248= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100452868; called by muse, mutect2, varscan2
- ISLR | c.1272C>T p.F424= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs765924842, COSV51435189; called by muse, mutect2, varscan2
- ITGAD | c.2181C>T p.I727= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV101210353; called by muse, mutect2, varscan2
- ITGAL | c.492G>A p.S164= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV63320657; called by muse, mutect2, varscan2
- ITGAL | c.597C>T p.S199= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100776101; called by muse, mutect2
- KCNE3 | c.229C>T p.L77= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100035537; called by muse, mutect2, varscan2
- KHDRBS2 | c.426G>C p.G142= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99831609; called by muse, mutect2
- KIF19 | c.2964C>T p.T988= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1373607612, COSV100738971; called by muse, mutect2
- KIR3DL2 | c.1092C>T p.C364= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1459245635, COSV99551809; called by muse, mutect2
- KRT3 | c.546C>T p.P182= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100526916; called by muse, mutect2, varscan2
- KRT6B | c.1164C>T p.I388= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52882585; called by muse, mutect2, varscan2
- KRTAP9-4 | c.393C>T p.R131= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as COSV100484846; called by muse, mutect2, varscan2
- L1TD1 | c.1278G>A p.E426= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100776541; called by muse, mutect2, varscan2
- LIMCH1 | c.909C>T p.S303= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100573478; called by muse, mutect2, varscan2
- LRP11 | c.843G>A p.T281= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs370621735, COSV99497739; called by muse, mutect2, varscan2
- MAGEB16 | c.339C>T p.L113= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV67874587; called by muse, mutect2, varscan2
- MAGEC1 | c.1542C>T p.L514= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV53583174; called by muse, mutect2, varscan2
- MAGEC2 | c.453C>T p.F151= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs147374365, COSV55997699; called by muse, mutect2, varscan2
- MED12 | c.408C>T p.F136= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100376509; called by muse, mutect2, varscan2
- MGAT3 | c.981C>T p.V327= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as COSV100361760; called by muse, mutect2, varscan2
- MINAR1 | c.1980T>A p.S660= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV100548696; called by muse, mutect2, varscan2
- MORC1 | c.2142G>A p.K714= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV99225314; called by muse, mutect2
- MTERF4 | c.819G>A p.R273= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs764913397, COSV99612344; called by muse, mutect2, varscan2
- MTMR1 | c.963A>G p.E321= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100953063; called by muse, mutect2
- MUC4 | c.2178C>T p.P726= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as COSV100639866; called by muse, mutect2
- MYH7 | c.1974G>A p.L658= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100805762; called by muse, mutect2
- MYO3B | c.1155C>T p.P385= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV100509369; called by muse, mutect2, varscan2
- MYO9B | c.3327C>T p.S1109= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101261388; called by muse, mutect2, varscan2
- NAALAD2 | c.399C>T p.Y133= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as rs1211644391, COSV100428120; called by muse, mutect2, varscan2
- NAT1 | c.96C>T p.I32= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as COSV56985204; called by muse, mutect2, varscan2
- NCF4 | c.87C>T p.I29= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs149998137; called by muse, mutect2
- NCKAP1L | c.1125C>T p.F375= | Silent (SNP) | VAF 4/75 reads (5%) | catalogued as COSV99514598; called by muse, mutect2
- NGFR | c.573C>T p.I191= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99412733; called by muse, mutect2, varscan2
- NLRC3 | c.360G>A p.R120= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs774884295, COSV100072504; called by mutect2, varscan2
- NOTCH4 | c.1269C>T p.G423= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV66679740; called by muse, mutect2
- OIT3 | c.1155G>A p.G385= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV61825009, COSV61825602; called by muse, mutect2
- OPRL1 | c.771C>T p.N257= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100401968; called by muse, mutect2, varscan2
- OR2F1 | c.216C>T p.S72= | Silent (SNP) | VAF 24/405 reads (6%) | catalogued as COSV101231288; called by muse, mutect2
- OR4K1 | c.21G>A p.S7= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs752575639, COSV99578707; called by muse, mutect2
- OR4K5 | c.726C>T p.S242= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV100262192, COSV60003827; called by muse, mutect2, varscan2
- OR52N5 | c.974G>A p.*325= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV100399608; called by muse, mutect2, varscan2
- OR56B1 | c.270C>T p.I90= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100402548; called by muse, mutect2, varscan2
- OR8D1 | c.879G>A p.R293= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV63441890, COSV63442241; called by muse, mutect2, varscan2
- OR8H3 | c.42C>T p.I14= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs267602991, COSV100538781, COSV57909870; called by muse, mutect2, varscan2
- PAMR1 | c.1071G>A p.R357= (on ENST00000619888 / NM_001001991.3; = p.R374= on NM_015430.4) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99552209; called by muse, mutect2, varscan2
- PAPPA2 | c.2322C>T p.T774= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs775792026, COSV62776085; called by muse, mutect2, varscan2
- PCDHA8 | c.81G>A p.G27= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs782300357, COSV100970506; called by muse, mutect2, varscan2
- PCDHB12 | c.1680C>T p.F560= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs781859924, COSV99506866; called by muse, mutect2, varscan2
- PCDHGB2 | c.1779G>A p.A593= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53983231, COSV99545106; called by muse, mutect2, varscan2
- PCDHGB6 | c.1356C>T p.F452= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV53905671; called by muse, mutect2, varscan2
- PCLO | c.5832G>A p.E1944= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV61646715; called by muse, mutect2
- PDGFA | c.291G>A p.K97= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100627270; called by muse, mutect2
- PHLDB2 | c.627G>A p.R209= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101208443; called by muse, mutect2
- PIBF1 | c.1359A>G p.V453= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100411278; called by muse, mutect2, varscan2
- PIGV | c.1425C>T p.F475= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99314781; called by muse, mutect2, varscan2
- PIK3CG | c.2637C>T p.I879= | Silent (SNP) | VAF 26/376 reads (7%) | catalogued as rs765560787, COSV100782621, COSV100783038; called by muse, mutect2
- PLAT | c.318C>T p.F106= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs138954051; called by mutect2, varscan2
- PLG | c.66G>A p.L22= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV99804314; called by muse, mutect2
- PRAMEF4 | c.561G>A p.L187= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as rs1208694640, COSV99339562; called by muse, mutect2, varscan2
- PROS1 | c.930T>A p.V310= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV101260305; called by muse, mutect2, varscan2
- PSMD7 | c.39C>T p.P13= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99542569; called by muse, mutect2
- PTBP1 | c.1251C>T p.P417= (on ENST00000349038 / NM_031991.4; = p.P443= on NM_002819.5) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100608402; called by muse, mutect2, varscan2
- PTPRT | c.963C>T p.I321= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV62007838; called by muse, mutect2
- RABGGTA | c.141C>T p.S47= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs375882032; called by muse, mutect2
- RAP2B | c.358C>T p.L120= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1281164670, COSV100058844; called by muse, mutect2, varscan2
- S100B | c.36C>T p.I12= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1349794639, COSV99388294; called by muse, mutect2, varscan2
- SAMD4A | c.243C>T p.S81= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99200584; called by muse, mutect2, varscan2
- SDSL | c.66G>A p.E22= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100615191; called by muse, mutect2
- SERPINB13 | c.1032G>A p.E344= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99500878; called by muse, mutect2
- SERPING1 | c.1212G>A p.T404= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs1215705678, CD087123, COSV99557859; called by muse, mutect2, varscan2
- SFXN3 | c.387C>T p.S129= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV99827382; called by muse, mutect2
- SH3BP5L | c.312C>T p.S104= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV63540058; called by muse, mutect2
- SLC25A12 | c.201C>T p.T67= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV99784745; called by muse, mutect2, varscan2
- SLC25A44 | c.495A>G p.Q165= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100849280; called by muse, mutect2
- SLC27A6 | c.1419C>T p.F473= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1222124494, COSV52488888; called by muse, mutect2
- SLC6A16 | c.1311C>T p.N437= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100242589; called by muse, mutect2, varscan2
- SLITRK5 | c.996G>A p.K332= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs962029333, COSV100280410; called by muse, mutect2, varscan2
- SSH1 | c.1095C>T p.T365= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs201438743, COSV100425365; called by muse, mutect2
- STK10 | c.1938G>A p.Q646= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99451023; called by muse, mutect2, varscan2
- STYK1 | c.939G>A p.G313= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99311629; called by muse, mutect2
- SYT10 | c.399C>T p.I133= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs757340341, COSV57346480; called by muse, mutect2
- TAF1A | c.939C>T p.F313= | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as COSV100600924; called by muse, mutect2
- TAOK2 | c.2496G>A p.G832= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV54233438, COSV99664024; called by muse, mutect2
- TK2 | c.99C>T p.V33= (on ENST00000299697; = p.V89= on NM_004614.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100228043; called by muse, mutect2, varscan2
- TM9SF4 | c.549C>T p.L183= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs1290198993, COSV99454036; called by muse, mutect2, varscan2
- TMEM164 | c.231G>A p.E77= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs767496795, COSV99911419; called by muse, mutect2, varscan2
- TMEM169 | c.612C>T p.I204= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV99824377; called by muse, mutect2, varscan2
- TMEM26 | c.726C>T p.F242= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs756705585, COSV99515465; called by muse, mutect2, varscan2
- TMEM42 | c.450C>T p.T150= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100189768; called by muse, mutect2, varscan2
- TNMD | c.342C>T p.F114= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs772338883, COSV65976962; called by muse, mutect2, varscan2
- TRANK1 | c.7341C>T p.F2447= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV57145062; called by muse, mutect2, varscan2
- TRAV13-2 | c.126C>T p.N42= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- TRIM35 | c.924C>T p.P308= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100542661; called by muse, mutect2, varscan2
- TRPV5 | c.1834C>T p.L612= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99520171; called by muse, mutect2
- TTC39C | c.1645C>T p.L549= (on ENST00000317571 / NM_001135993.2; = p.L488= on NM_153211.4) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100455208; called by muse, mutect2, varscan2
- TTN | c.54339G>A p.K18113= (on ENST00000591111; = p.K10689= on NM_003319.4) | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs1340386200, COSV100598135; called by muse, mutect2, varscan2
- VWF | c.2484C>T p.P828= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99778254; called by muse, mutect2
- YKT6 | c.390C>T p.Y130= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99790503; called by muse, mutect2
- ZNF280B | c.1596C>T p.P532= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100840200, COSV64529053; called by muse, mutect2
- ZNF568 | c.492G>A p.L164= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100451194; called by muse, mutect2
- ZNF682 | c.435C>T p.F145= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV62066164; called by muse, mutect2, varscan2
- ZNF781 | c.504G>A p.L168= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV62200912; called by muse, mutect2
- GCNT2 | c.926-34774C>T | Intron (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99399105; called by muse, mutect2, varscan2
- OR2W5 | n.945C>T | RNA (SNP) | VAF 14/76 reads (18%) | catalogued as rs267598469; called by muse, mutect2, varscan2
- RORA | c.196+63644G>A | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99832264; called by muse, mutect2, varscan2
- RPL26P30 | n.578C>T | RNA (SNP) | VAF 17/150 reads (11%) | catalogued as rs992153340; called by muse, mutect2, varscan2
- SLC22A17 | n.808C>T | RNA (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99248579; called by muse, mutect2
- SNORD115-29 | n.55C>T | RNA (SNP) | VAF 46/365 reads (13%) | called by muse, mutect2, varscan2
- TCF12 | c.1189-809T>A | Intron (SNP) | VAF 19/82 reads (23%) | catalogued as COSV99976543; called by muse, mutect2, varscan2
- TTN | c.10360+3983C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100598142; called by muse, mutect2
- ZBTB16 | c.*1A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100251079; called by muse, mutect2
